Gene-level copy-number profile of tumor specimen TCGA-AC-A2FB-01A from TCGA case TCGA-AC-A2FB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.3 years (23,851 days).
Specimen TCGA-AC-A2FB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ebef629e-e465-4ef3-84db-81ff8522b7f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A2FB-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6a9a43b-f00a-4028-88c2-ae49bbb99e32

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 429; copy number 2: 59,140; copy number 3: 38; copy number 4: 81; copy number 5: 51; copy number 8: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A2FB-01A-11D-A17C-01): tumor purity 0.23, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 126 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:70,078,302–71,252,577, 24 genes, copy number 8 (within-gene range 2–8): ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr17:29,855,759–30,831,318, 51 genes, copy number 5: RPL9P30, AC104982.2, AC104982.1, EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2, AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5, SLC6A4, AC104984.1, AC104984.4, SNORD63, BLMH, RNU6-1267P, TMIGD1, Y_RNA, RNU6-990P, CPD, GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1, RN7SL316P, SUZ12P1, AC127024.7, AC127024.3, AC127024.2, AC127024.8, CRLF3, AC127024.4, AC127024.5, AC127024.6, AC127024.1.
- chr17:38,765,689–39,877,896, 51 genes, copy number 8 (within-gene range 3–8): PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21, AC110749.1, LASP1, AC006441.1, MIR6779, AC006441.3, LINC00672, FBXO47, AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.

Autosomal genes at a single copy (total copy number 1): 284. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
